MMRF case MMRF_1540 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2528b762-2df3-46fd-ae3c-2bf671c590fc

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 527 days (1.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.3 years (21,287 days); ISS stage: II; Days to last known disease status: 527 days (1.4 years); Days to last follow up: 527 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 518 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 527.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -41: M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 92.1 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 39.4 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 5.4 µg/mL; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.54 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.55 mmol/L; Albumin 33 g/L; Total Protein 9.9 g/dL; Glucose 4.57 mmol/L; C-Reactive Protein 8.2 mg/dL.
- Day 57: M Protein 3.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.736 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 222 mg/dL; Immunoglobulin G 3.07 g/L; Immunoglobulin A 43.9 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.68 mmol/L; Albumin 34 g/L; Total Protein 11.3 g/dL; Glucose 5.06 mmol/L.
- Day 141 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.559 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.4 mg/dL; Immunoglobulin G 4.03 g/L; Immunoglobulin A 3.95 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.95 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 3.14 mmol/L.
- Day 225 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.735 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.192 mg/dL; Immunoglobulin G 3.97 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.95 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 316 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.838 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 3.5 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.5 mmol/L.
- Day 420 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.76 mg/dL; Immunoglobulin G 6.09 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.33 mmol/L.
- Day 511 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.568 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.38 mg/dL; Immunoglobulin G 5.32 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 10.6 µkat/L; Hemoglobin 10.9 mmol/L; Leukocytes 11.3 ×10⁹/L; Absolute Neutrophil 9.83 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 407 µmol/L; Blood Urea Nitrogen 21.4 mmol/L; Calcium 1.98 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 10 mmol/L.

Other clinical attributes
- Day -41: Weight: 42 kg; Height: 157 cm.

Biospecimens (2 samples)
- Sample MMRF_1540_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -41 days.
- Sample MMRF_1540_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -41 days.
